Gene-level copy-number profile of tumor specimen TCGA-55-A48Y-01A from TCGA case TCGA-55-A48Y, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.5 years (25,384 days).
Specimen TCGA-55-A48Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.69e9946e-4f28-41ba-bf4c-226bf5cbf030.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A48Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba82a6de-5c3b-45e0-b7f9-bbbeb7f65a70

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,508; copy number 3: 306; copy number 4: 39,965; copy number 5: 2,189; copy number 6: 6,242; copy number 7: 232; copy number 8: 331; copy number 9: 41; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A48Y-01A-11D-A24C-01): tumor purity 0.36, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 45 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:152,243,828–152,465,780, 1 gene, copy number 11 (within-gene range 4–11): MBNL1.
- chr3:152,339,695–152,496,813, 3 genes, copy number 11: TMEM14EP, Y_RNA, AC026347.1.
- chr8:128,323,131–128,564,679, 2 genes, copy number 9: AC100822.1, LINC00824.
- chr12:68,610,855–68,671,901, 1 gene, copy number 9 (within-gene range 5–9): RAP1B.
- chr12:68,642,519–68,971,570, 15 genes, copy number 9 (within-gene range 4–9): ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:113,195,441–113,480,624, 10 genes, copy number 9: IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1.
- chr18:3,466,250–4,455,307, 13 genes, copy number 9 (within-gene range 4–9): GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
